Somatic mutation profile of tumor specimen C3L-01053-01 (aliquot CPT0123860009) from CPTAC case C3L-01053, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 76.1 years (27,798 days).
Specimen C3L-01053-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0708d9c5-2f6b-4bad-9181-7d75dc8925d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01053-31 (Blood Derived Normal), aliquot CPT0124900002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c8e1318-8cbc-4e90-90f0-0155c382401e

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 3, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OR5H1 | c.781G>A p.G261S | Missense Mutation (SNP) | VAF 14/295 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.21); catalogued as rs1403816139; called by muse, mutect2
- FLNA | c.3404A>G p.N1135S | Missense Mutation (SNP) | VAF 17/446 reads (4%) | SIFT tolerated (0.89); PolyPhen benign (0.003); called by muse, mutect2
- P2RY1 | c.740A>C p.K247T | Missense Mutation (SNP) | VAF 7/188 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.112); called by muse, mutect2
- BCLAF3 | c.2052C>G p.G684= (on ENST00000379682 / NM_001367774.1; = p.G655= on NM_198279.3) | Silent (SNP) | VAF 9/204 reads (4%) | called by muse, mutect2
- OR1J1 | c.576C>T p.T192= | Silent (SNP) | VAF 18/410 reads (4%) | called by muse, mutect2
- ZNF729 | c.1086C>A p.T362= | Silent (SNP) | VAF 10/186 reads (5%) | catalogued as rs1288152459; called by muse, mutect2
